Surgical pathology report (de-identified scan), TCGA case TCGA-EE-A2A0, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site University of Sydney, specimen TCGA-EE-A2A0-06A (Metastatic).

[page 1 of 3]
DOB/Age/Se:
Location:
Requested by:
Requested on:
Specimen Rcvd:
Accession No.:
Contact to:

HISTOPATHOLOGY SUPPLEMENTARY REPORT

SUPPLEMENTARY MACROSCOPIC DESCRIPTION

2M-R. Further lymph nodes.

SUPPLEMENTARY REPORT

2. An additional four lymph nodes were retrieved after further examination of the specimen. One small lymph node (2N) shows metastatic melanoma, present in the subcapsular sinus. These collections of highly atypical cells show positive staining for S100, HMB45 and Melan A.

This changes the previous report, as there is now a total of 12 lymph nodes, one of which shows metastatic melanoma (1/12).

SUPPLEMENTARY SUMMARY

1. Left groin lymph nodes - METASTATIC MELANOMA IN FOUR OUT OF TEN LYMPH NODES (4/10).

2. Left iliac and obturator lymph nodes - METASTATIC MELANOMA IN ONE OF TWELVE LYMPH NODES (1/12).

REPORTED BY Dr.

1CD-0-3

Melanoma, NOS 8720/3

Site: lymph node, groin C77.4

6/12/11

6/12/11

A Unit of:

Print

This fax was received by

[page 2 of 3]
DOB/Age/Sex:
Location:
Requested by:
Requested on:
Specimen Rcvd:
Accession No.:
Copies to:

HISTOPATHOLOGY REPORT

CLINICAL DETAILS

Metastatic melanoma. - palpable left groin tumour, FNA -> melanoma. - ilio - inguinal dissection.
Hisopathology.- tumour bank.

MACROSCOPIC DESCRIPTION

(Dr

Two specimens received.

1. "LEFT GROIN CONTENTS - STAPLE UPPER". An oriented ellipse of skin and attached subcutaneous fibro fatty tissue 260 x 120 x 80mm in depth orientated with staple marking upper. (The specimen was previously sampled for tumour banking). The specimen is dissected from upper to lower. There are several lymph nodes identified including two large nodes up to 60 and 70mm across with solid pale tan to grey cut surface.

- A & B. Large lymph node.
- C & D. One bisected lymph node each.
- E. Three lymph nodes.
- F & G. One bisected lymph node.
- H. One lymph node.
- I. One lymph node.
- K & L. One lymph node.
- M. Representative section from the skin.
- N. ?One lymph node

2. "LEFT ILIAC + OBTURATOR LYMPH NODES". An irregular piece of fatty tissue 90 x 50 x 35mm. There are eight lymph nodes identified up to 24mm across.

- A. One bisected lymph node.
- B. One lymph node.
- C & D. One bisected lymph node.
- E-H. One bisected lymph node each.
- J-L. Four sections of one lymph node.

MICROSCOPIC REPORT

1. "LEFT GROIN CONTENTS - STAPLE UPPER".

A total of ten lymph nodes were retrieved, of which four show complete replacement of the lymph node by metastatic melanoma. This is characterised by large, pleomorphic epithelioid cells with variable oval nuclei and prominent nucleoli. Numerous mitoses are seen. The cells have moderate amounts of amphophilic cytoplasm. There are several areas of necrosis. Immunohistochemical staining shows that the tumour cells are positive for S100, HMB45, and Melan A. Focal extra nodal spread is seen up to 2mm from the capsule. The skin is unremarkable. (4/10).

2. "LEFT ILIAC + OBTURATOR LYMPH NODES".

A Unit of

Print

This fax was received

[page 3 of 3]
From: --

Page:

Date:

Requested by

MRN/Name:

Location:

Accession:

HISTOPATHOLOGY REPORT

Eight lymph nodes with no evidence of malignancy (0/8).

COMMENT

2. The specimen is being reexamined for further lymph nodes and a supplementary report will follow.

SUMMARY

1. Left groin lymph nodes - METASTATIC MELANOMA IN FOUR OUT OF TEN LYMPH NODES (4/10).

2. Left iliac and obturator lymph nodes - No evidence of malignancy in eight lymph nodes (0/8).

REPORTED BY: Dr.

Source: NCI Genomic Data Commons file d1fd46c0-71f8-4b7e-85b7-f1ce8c2f79a6 (TCGA-EE-A2A0.5A3258EA-F7DF-478F-A079-D12BC543078E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).